Somatic mutation profile of tumor specimen C3N-00545-01 (aliquot CPT0066890006) from CPTAC case C3N-00545, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 59.2 years (21,607 days).
Specimen C3N-00545-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d00a6bd-6c17-4d73-be03-1c01389465d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00545-71 (Blood Derived Normal), aliquot CPT0067010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a1142f3-270c-4878-b3f3-fe0185e3e25f

The open-access MAF lists 365 somatic variants for this specimen: 250 protein-altering or splice-affecting, 58 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 58, Intron 33, Nonsense Mutation 16, RNA 11, Frame Shift Del 9, 5'UTR 6, Splice Site 5, 3'Flank 3, 3'UTR 3, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 43/197 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59318528; called by muse, mutect2, varscan2
- ADCY1 | c.2203C>A p.L735M | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV52034981, COSV52039400; called by muse, mutect2
- AGBL1 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101222919; called by muse, mutect2
- ALPK2 | c.4105G>A p.V1369I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs760732329; called by muse, mutect2, varscan2
- AMPH | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57749717; called by muse, mutect2
- CACNA1E | c.5244G>T p.W1748C | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62401840; called by muse, mutect2, varscan2
- CACNB1 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.202); catalogued as COSV59999992; called by muse, mutect2
- CNBD1 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1312301463; called by muse, mutect2
- CNTN1 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365083104; called by muse, mutect2
- COL11A1 | c.1350+1G>T p.X450_splice | Splice Site (SNP) | VAF 6/95 reads (6%) | catalogued as COSV100617330, COSV62196797; called by muse, mutect2
- COL13A1 | c.383del p.G128Efs*67 | Frame Shift Del (DEL) | VAF 11/149 reads (7%) | catalogued as COSV100637468; called by mutect2, pindel
- COL18A1 | c.2242G>A p.V748M (on ENST00000359759 / NM_130444.3; = p.V513M on NM_030582.4) | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs367882523; called by muse, mutect2
- CYP2C9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/156 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs150891702, COSV53247038; called by muse, mutect2, varscan2
- CYP7B1 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 21/133 reads (16%) | catalogued as CM1514278; called by muse, mutect2, varscan2
- DNMT1 | c.4445G>T p.G1482V | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746932608; called by muse, mutect2, varscan2
- FAM98B | c.802A>G p.M268V | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs1032366853; called by muse, mutect2, varscan2
- FAT3 | c.12669G>T p.Q4223H | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV53154620; called by muse, mutect2
- FCGR2B | c.893C>A p.P298Q | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777983386, COSV52682376; called by muse, mutect2, varscan2
- FCRLA | c.362G>T p.R121L (on ENST00000367959; = p.R98L on NM_032738.4) | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99375701; called by muse, mutect2, varscan2
- FIS1 | c.396G>T p.M132I | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99778874; called by muse, mutect2, varscan2
- GPATCH1 | c.1789G>T p.A597S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767956563; called by muse, mutect2, varscan2
- GRIN2B | c.3403G>T p.D1135Y | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV74207234; called by muse, mutect2, varscan2
- GRIN2B | c.1147T>A p.S383T | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs199671864, COSV74207529; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- GRM8 | c.1265A>G p.D422G | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV100283537, COSV58879861; called by muse, mutect2
- HHAT | c.556del p.E186Sfs*52 | Frame Shift Del (DEL) | VAF 50/474 reads (11%) | catalogued as COSV99805159; called by mutect2, pindel
- HMCN2 | c.5386G>T p.G1796C | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320454575; called by muse, mutect2, varscan2
- IMPG2 | c.2941A>G p.M981V | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs926472701; called by muse, mutect2
- ITLN2 | c.320C>G p.T107R | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63537732; called by muse, mutect2, varscan2
- JUP | c.71C>G p.S24W | Missense Mutation (SNP) | VAF 26/658 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM103173, COSV60278251; called by muse, mutect2
- KLHL34 | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV101069961; called by muse, mutect2, varscan2
- KRTAP13-2 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1228452988; called by muse, mutect2
- LMLN | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs868151000; called by muse, mutect2, varscan2
- LRRC15 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 28/378 reads (7%) | catalogued as rs755593413, COSV61649909; called by muse, mutect2
- LRRIQ3 | c.1105G>T p.V369L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV63041428; called by muse, mutect2
- MAEL | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs756146420, COSV100901555; called by muse, mutect2, varscan2
- MAGEC1 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV53581631; called by muse, mutect2
- MROH2A | c.2591C>A p.P864Q | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV67680924; called by muse, mutect2
- MYO16 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 21/198 reads (11%) | catalogued as COSV51814391; called by muse, mutect2, varscan2
- NAP1L2 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV65172988; called by muse, mutect2, varscan2
- NOTCH4 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as COSV66684326; called by muse, mutect2, varscan2
- NR0B1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.876); catalogued as rs761749382; called by muse, mutect2, varscan2
- OR8K3 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57131466; called by muse, mutect2, varscan2
- OTOG | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 39/341 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1378612394; called by muse, mutect2, varscan2
- PAMR1 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.1); catalogued as rs751297404; called by muse, mutect2
- PRICKLE2 | c.1172G>T p.R391L (on ENST00000295902; = p.R335L on NM_198859.4) | Missense Mutation (SNP) | VAF 54/848 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55762823; called by muse, mutect2
- PTPRQ | c.4055C>T p.T1352I (on ENST00000616559; = p.T1310I on NM_001145026.2) | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as rs1170285261; called by muse, mutect2
- RP1L1 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs767785821, COSV61445796; called by muse, mutect2, varscan2
- RUNX1T1 | c.1680G>T p.Q560H (on ENST00000265814 / NM_001198628.1; = p.Q533H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/562 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV56137349; called by muse, mutect2, varscan2
- SAMD9L | c.1442G>T p.W481L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs763034101, COSV59080895, COSV59080935; called by muse, mutect2, varscan2
- SH2B1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs745614421; called by mutect2, varscan2
- SLC25A48 | c.871G>T p.V291L (on ENST00000650267; = p.G240= on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.079); catalogued as rs1480932494; called by muse, mutect2
- SLC6A17 | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as rs1334090420; called by muse, mutect2
- SLITRK1 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 25/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100999859; called by muse, mutect2
- SMARCA4 | c.2651A>T p.H884L | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60793246, COSV60804891; called by muse, mutect2
- SOX17 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs575311838; called by muse, mutect2, varscan2
- SPATA18 | c.1493G>C p.R498P | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV54644915, COSV54647498; called by muse, mutect2
- STXBP5 | c.1480A>G p.T494A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs761855511; called by muse, mutect2, varscan2
- STYXL2 | c.2203C>T p.L735F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54802904; called by muse, mutect2
- TFPI | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1462616601; called by muse, mutect2
- TLR4 | c.645G>T p.M215I (on ENST00000355622 / NM_138554.5; = p.M175I on NM_003266.4) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62923936; called by muse, mutect2, varscan2
- TMEM132D | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 32/351 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV101396153; called by muse, mutect2
- TNFSF18 | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as rs1349465717; called by muse, mutect2, varscan2
- TPR | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1395168961; called by muse, mutect2
- UGT2B17 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100497315; called by muse, mutect2, varscan2
- ZFPM2 | c.2622G>T p.Q874H | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65873028; called by muse, mutect2
- ZNF587B | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100332180; called by muse, mutect2
- ZNF716 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV70781758; called by muse, mutect2, varscan2
- ZNF799 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs544617815; called by muse, mutect2, varscan2
- ZNF99 | c.2015C>A p.T672N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs769685323, COSV68055549; called by muse, mutect2, varscan2
- ZP4 | c.1041C>A p.Y347* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV100850506; called by muse, mutect2
- AC005833.1 | c.1026A>T p.R342S | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS13 | c.2900G>T p.G967V | Missense Mutation (SNP) | VAF 40/560 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ADGRL3 | c.465G>T p.M155I (on ENST00000506720 / NM_001322402.2; = p.M87I on NM_015236.6) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.205); called by muse, mutect2
- AFF2 | c.2260C>A p.L754M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- AL592490.1 | c.2123A>T p.Y708F | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALDH9A1 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- AMBRA1 | c.3567C>A p.H1189Q (on ENST00000458649 / NM_001367468.1; = p.H1099Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- APCS | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2
- ATP12A | c.2423A>T p.Y808F | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ATP6V0A4 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 64/558 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ATXN7L2 | c.1486G>T p.A496S | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BMPER | c.2019G>T p.K673N | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- BNC1 | c.1343del p.P448Qfs*35 | Frame Shift Del (DEL) | VAF 40/294 reads (14%) | called by mutect2, pindel, varscan2
- BPIFB3 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2
- BRD1 | c.387_397del p.P130Qfs*24 | Frame Shift Del (DEL) | VAF 22/202 reads (11%) | called by mutect2, pindel
- BTBD17 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.294); called by muse, mutect2
- BTNL9 | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2
- C1QTNF6 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.299); called by muse, mutect2
- CCDC85A | c.990G>T p.R330S | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CCDC88A | c.2284G>C p.D762H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CDH16 | c.1621C>G p.P541A | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by muse, mutect2
- CDK14 | c.1394C>G p.S465* (on ENST00000380050 / NM_001287135.2; = p.S447* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- CEP89 | c.1268+1del p.X423_splice | Splice Site (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CES3 | c.603T>A p.D201E | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN3 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CNGB3 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL6A6 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRYGS | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 35/337 reads (10%) | called by muse, mutect2
- CSAG1 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSMD2 | c.5305G>T p.G1769W | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUBN | c.2503G>T p.V835L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- DCAF1 | c.2072dup p.D693Rfs*2 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | called by mutect2, pindel
- DDX3Y | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DEFA6 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DGLUCY | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- DLGAP3 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- DMGDH | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH3 | c.1908T>A p.D636E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.1921G>C p.G641R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.392); called by muse, mutect2
- DOCK2 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSC3 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DYDC1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ELMO1 | c.450-2A>T p.X150_splice | Splice Site (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- EMILIN2 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ENOSF1 | c.1006G>T p.A336S (on ENST00000340116 / NM_001354066.2; = p.A288S on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- EPHB4 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHB6 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ERAS | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERBB3 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVX1 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- FAM47C | c.142dup p.W48Lfs*19 | Frame Shift Ins (INS) | VAF 28/192 reads (15%) | called by mutect2, pindel, varscan2
- FARP1 | c.1767A>T p.E589D | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FARP2 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO4 | c.653G>C p.G218A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FER1L6 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLG | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 28/647 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- FRMPD4 | c.987A>G p.I329M | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2
- FTCD | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAS1 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GORASP2 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.073); called by muse, mutect2
- GPR12 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIN1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- GUSB | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 59/595 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- HDC | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 42/432 reads (10%) | called by muse, mutect2
- HERC4 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HNF1A | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 43/380 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HS3ST3B1 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IFNA21 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- IGKV3D-15 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.396); called by muse, mutect2
- IMPG2 | c.1811G>C p.G604A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- KANK4 | c.1251C>A p.D417E | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2
- KCNK3 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- KDM5C | c.1834G>C p.A612P | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KIF26A | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- KLHL4 | c.35A>T p.K12I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- L3MBTL3 | c.2048T>G p.L683R | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- LAMA2 | c.7595C>A p.P2532H | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); called by muse, mutect2
- LAMC3 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 91/630 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCP1 | c.1495A>T p.M499L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, varscan2
- LIMK1 | c.1111A>T p.I371F | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- LRIT1 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC4C | c.1746A>T p.E582D | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC7 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- LRRK1 | c.5824G>T p.G1942C | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAN1B1 | c.616A>T p.I206F | Missense Mutation (SNP) | VAF 18/660 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.391); called by muse, mutect2
- MAPK13 | c.673G>T p.G225W | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MEGF8 | c.7604C>T p.P2535L (on ENST00000251268 / NM_001271938.2; = p.P2468L on NM_001410.3) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- MFNG | c.303G>T p.L101= | Splice Region (SNP) | VAF 19/238 reads (8%) | called by muse, mutect2
- MOXD1 | c.836G>C p.G279A | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- MPP1 | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- MS4A4E | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MUC16 | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- MYH13 | c.5799C>A p.S1933R | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- MYRF | c.856C>A p.P286T (on ENST00000278836 / NM_001127392.3; = p.P277T on NM_013279.4) | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- NANOG | c.20del p.C7Ffs*21 | Frame Shift Del (DEL) | VAF 23/152 reads (15%) | called by mutect2, pindel
- NAV3 | c.6182del p.G2061Efs*13 (on ENST00000397909 / NM_001024383.2; = p.G2039Efs*13 on NM_014903.6) | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | called by mutect2, pindel
- NID1 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2
- NKX2-4 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- NPHS2 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- NPR3 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NRXN2 | c.2060C>A p.S687Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- NXPH2 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OBSCN | c.3626G>T p.S1209I | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- OR13C8 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR2S2 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 46/488 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- OR4A15 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR6K3 | c.436C>T p.L146F (on ENST00000368146; = p.L130F on NM_001005327.2) | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PADI3 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- PADI4 | c.1222G>T p.G408W | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA7 | c.2191G>T p.G731C | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PGS1 | c.1349A>T p.E450V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.254); called by muse, mutect2
- PIEZO2 | c.992C>A p.S331* | Nonsense Mutation (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- PIK3R4 | c.483G>T p.W161C | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PINX1 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- PKHD1 | c.5554C>G p.H1852D | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.193); called by muse, mutect2
- PKHD1 | c.3008del p.G1003Vfs*13 | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel
- PLEKHA5 | c.2411A>T p.Y804F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLEKHA6 | c.2362G>T p.V788L | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- POP7 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.099); called by muse, mutect2
- POTEE | c.510C>A p.D170E | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2
- POU5F1B | c.706A>T p.S236C | Missense Mutation (SNP) | VAF 34/726 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP4R3C | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2
- PRAMEF20 | c.509G>T p.W170L | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRPF8 | c.5851A>G p.K1951E | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- PRRC2A | c.4481G>T p.G1494V | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTCH2 | c.2491C>T p.Q831* | Nonsense Mutation (SNP) | VAF 26/670 reads (4%) | called by muse, mutect2
- PTPN23 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- PTPRD | c.1972A>C p.K658Q | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RASGRF1 | c.3730-2A>C p.X1244_splice | Splice Site (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- RCC1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- RET | c.1324C>A p.L442M | Missense Mutation (SNP) | VAF 63/539 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX1 | c.773A>T p.K258I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROBO4 | c.2336G>T p.S779I | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RUBCNL | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.174); called by muse, mutect2
- RUNX3 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RYR1 | c.10686+6C>T | Splice Region (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- SAGE1 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- SALL3 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, varscan2
- SCN5A | c.4106G>C p.G1369A (on ENST00000333535 / NM_198056.3; = p.G1368A on NM_000335.5) | Missense Mutation (SNP) | VAF 9/300 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.414); called by muse, mutect2
- SEC16B | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2
- SEC16B | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2
- SETBP1 | c.1721C>A p.T574K | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETBP1 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SF3B4 | c.623A>T p.H208L | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SHANK1 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SI | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A8 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- SLC25A21 | c.530del p.G177Dfs*20 | Frame Shift Del (DEL) | VAF 29/152 reads (19%) | called by mutect2, pindel, varscan2
- SLC35A2 | c.660T>A p.F220L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2
- SLC6A12 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ST18 | c.671C>A p.T224K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STK11IP | c.1463A>T p.E488V | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- STXBP5L | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TEDC1 | c.1061G>T p.G354V (on ENST00000392523 / NM_001367178.1; = p.G285V on NM_001134875.1) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TENM4 | c.6929T>A p.L2310Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEP1 | c.5225A>T p.E1742V | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TEX13C | c.2974C>G p.P992A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- TMC3 | c.1284del p.N430Ifs*7 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- TMTC1 | c.1101G>T p.L367F (on ENST00000539277 / NM_001193451.2; = p.L259F on NM_175861.3) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, varscan2
- TMX4 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TNS3 | c.4240G>A p.V1414M | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2
- TRIM32 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 40/630 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- TRIM58 | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTC22 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- UBASH3A | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2
- USH1G | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- USP16 | c.491T>G p.L164* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- USP34 | c.4378G>C p.G1460R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- VEZT | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- VIPR2 | c.1046T>A p.I349N | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.124); called by muse, mutect2
- VPS13B | c.2176C>T p.L726F | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WNK2 | c.5101G>T p.A1701S (on ENST00000297954 / NM_001282394.1; = p.A1664S on NM_006648.3) | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.815); called by muse, mutect2
- YLPM1 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- ZC3H12B | c.2429C>A p.A810E | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, varscan2
- ZNF257 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 17/187 reads (9%) | called by muse, mutect2
- ZNF41 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF729 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF780A | c.1657G>T p.G553* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- ZNF845 | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AANAT | c.123C>A p.T41= | Silent (SNP) | VAF 24/285 reads (8%) | called by muse, mutect2
- AMOT | c.1209A>T p.P403= | Silent (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- ANK2 | c.8376T>C p.G2792= | Silent (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- ANKRD60 | c.873C>T p.S291= | Silent (SNP) | VAF 38/307 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.4263C>T p.D1421= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as rs151281059; called by muse, mutect2
- ARL6IP4 | c.978G>T p.L326= (on ENST00000315580 / NM_018694.3; = p.L307= on NM_016638.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- ASXL3 | c.4461G>C p.L1487= | Silent (SNP) | VAF 16/219 reads (7%) | called by muse, mutect2
- ATP1A2 | c.2136G>T p.T712= | Silent (SNP) | VAF 40/293 reads (14%) | called by muse, mutect2, varscan2
- AVPR1B | c.1161C>A p.A387= | Silent (SNP) | VAF 59/506 reads (12%) | called by muse, mutect2, varscan2
- BBS10 | c.1494A>G p.V498= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs1048483339; called by muse, mutect2
- BSND | c.564C>A p.P188= | Silent (SNP) | VAF 11/232 reads (5%) | catalogued as COSV100987637; called by muse, mutect2
- CDH23 | c.504C>A p.L168= | Silent (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2
- CDH6 | c.2082C>T p.P694= | Silent (SNP) | VAF 25/232 reads (11%) | catalogued as rs764269155, COSV54078647, COSV99420279; called by muse, mutect2, varscan2
- CNGB1 | c.1368A>T p.S456= | Silent (SNP) | VAF 21/572 reads (4%) | called by muse, mutect2
- CPA3 | c.274T>C p.L92= | Silent (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2
- CSMD2 | c.6762G>A p.R2254= | Silent (SNP) | VAF 12/282 reads (4%) | catalogued as rs1264473397; called by muse, mutect2
- CTNND2 | c.2598G>T p.A866= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as COSV58881028; called by muse, mutect2
- DCHS1 | c.8292A>G p.T2764= | Silent (SNP) | VAF 51/428 reads (12%) | catalogued as rs763012228; ClinVar: benign; called by muse, mutect2, varscan2
- DLGAP3 | c.570G>T p.P190= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as COSV99332050; called by muse, mutect2
- E2F8 | c.1674C>T p.S558= | Silent (SNP) | VAF 42/478 reads (9%) | catalogued as rs763917035; called by muse, mutect2
- ERN2 | c.675G>T p.L225= | Silent (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- FAT3 | c.1800C>G p.V600= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV53094939, COSV53152256; called by muse, mutect2
- FDXR | c.828G>C p.L276= (on ENST00000293195 / NM_024417.5; = p.L282= on NM_004110.6) | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- FGF23 | c.609G>T p.P203= | Silent (SNP) | VAF 51/221 reads (23%) | catalogued as COSV99426727; called by muse, mutect2, varscan2
- GDF10 | c.840C>T p.P280= | Silent (SNP) | VAF 37/193 reads (19%) | called by muse, mutect2, varscan2
- GPM6A | c.297G>A p.L99= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV54533479; called by muse, mutect2
- GPR26 | c.213G>T p.R71= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- GPR26 | c.700C>A p.R234= | Silent (SNP) | VAF 27/268 reads (10%) | catalogued as rs777716254; called by muse, mutect2
- HSP90AB1 | c.555T>C p.L185= | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- ILDR2 | c.585G>C p.L195= | Silent (SNP) | VAF 38/335 reads (11%) | catalogued as COSV99614113; called by muse, mutect2, varscan2
- JADE3 | c.378C>T p.I126= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- KCNA5 | c.1728C>G p.A576= | Silent (SNP) | VAF 37/398 reads (9%) | called by muse, mutect2
- KNG1 | c.912G>T p.V304= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- MAGEB6 | c.1033C>A p.R345= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV100983666, COSV66872362; called by muse, mutect2, varscan2
- MED12 | c.888G>T p.R296= | Silent (SNP) | VAF 43/175 reads (25%) | called by muse, mutect2, varscan2
- MEGF9 | c.1350C>T p.I450= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, varscan2
- MISP | c.1323C>T p.F441= | Silent (SNP) | VAF 35/375 reads (9%) | catalogued as rs185675116; called by muse, mutect2
- MRGPRX2 | c.216C>A p.A72= | Silent (SNP) | VAF 22/233 reads (9%) | catalogued as rs758641595; called by muse, mutect2
- MUC12 | c.16207C>T p.L5403= (on ENST00000379442; = p.L5260= on NM_001164462.1) | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- MYO1F | c.555C>A p.G185= | Silent (SNP) | VAF 42/386 reads (11%) | called by muse, mutect2, varscan2
- MYO7A | c.3267C>A p.A1089= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as COSV101289167; called by muse, mutect2
- NF1 | c.6399G>T p.L2133= (on ENST00000358273 / NM_001042492.3; = p.L2112= on NM_000267.3) | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as CD1311362; called by muse, mutect2
- OR2G3 | c.729C>A p.S243= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV100180538; called by muse, mutect2
- PCDHA2 | c.1225C>T p.L409= | Silent (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- PCDHGA3 | c.540G>T p.L180= | Silent (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- PCSK4 | c.741G>A p.L247= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs1400431214; called by muse, mutect2, varscan2
- PLCXD3 | c.930C>A p.L310= | Silent (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- POLM | c.846C>T p.H282= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- SCN4A | c.2148G>T p.V716= | Silent (SNP) | VAF 46/434 reads (11%) | catalogued as COSV101438337; called by muse, mutect2
- SLC6A17 | c.1932C>A p.L644= | Silent (SNP) | VAF 20/320 reads (6%) | catalogued as rs1162798273; called by muse, mutect2
- STYXL2 | c.1356G>A p.K452= | Silent (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- THEM4 | c.441A>G p.P147= | Silent (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- TMC2 | c.2610C>T p.H870= | Silent (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- TOR4A | c.156C>T p.D52= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as rs1395288149; called by muse, mutect2, varscan2
- TRGV4 | c.144C>T p.T48= | Silent (SNP) | VAF 47/429 reads (11%) | catalogued as rs746908068; called by muse, mutect2, varscan2
- TRPS1 | c.3201T>A p.P1067= (on ENST00000220888 / NM_001330599.2; = p.P1080= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/324 reads (13%) | called by muse, mutect2, varscan2
- VIPR2 | c.1044C>A p.P348= | Silent (SNP) | VAF 28/347 reads (8%) | called by muse, mutect2
- ZBED6 | c.357A>T p.I119= | Silent (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- AC002511.3 | n.392T>A | RNA (SNP) | VAF 27/236 reads (11%) | called by muse, varscan2
- AC024940.1 | n.4877C>A | RNA (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3521C>T | RNA (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- ADAM23 | c.2360-4050A>T | Intron (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- AOAH | c.*84C>A | 3'UTR (SNP) | VAF 40/432 reads (9%) | called by muse, mutect2
- AP4M1 | c.463-30T>G | Intron (SNP) | VAF 28/743 reads (4%) | called by muse, mutect2
- ARHGEF4 | chr2:130916435 A>T | 5'Flank (SNP) | VAF 16/120 reads (13%) | catalogued as rs909596269; called by muse, mutect2, varscan2
- ASXL1 | c.57+463G>T | Intron (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- C10orf90 | c.1243+1170T>A | Intron (SNP) | VAF 7/47 reads (15%) | catalogued as rs1462073276; called by muse, mutect2
- C15orf40 | c.366+75A>C | Intron (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- C3P1 | n.3465C>T | RNA (SNP) | VAF 31/417 reads (7%) | catalogued as rs773425061; called by muse, mutect2
- CAPRIN2 | c.2318-303A>G | Intron (SNP) | VAF 7/102 reads (7%) | catalogued as rs1189313059; called by muse, mutect2
- CCDC74B | c.296-204C>T | Intron (SNP) | VAF 25/286 reads (9%) | catalogued as rs1252625017; called by muse, mutect2
- CHP2 | c.140+14G>T | Intron (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- DACT3 | c.499+14G>C | Intron (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- FAM161A | c.*494G>T | 3'UTR (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- FCSK | c.235-72T>G | Intron (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- FGFR1 | c.-3G>T | 5'UTR (SNP) | VAF 22/278 reads (8%) | catalogued as COSV100248589, COSV58337863; called by muse, mutect2
- FLJ40194 | n.355T>C | RNA (SNP) | VAF 27/266 reads (10%) | catalogued as rs748895517; called by muse, mutect2, varscan2
- FRMD8P1 | n.855C>A | RNA (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- GRAMD1B | c.2127+136G>T | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, varscan2
- GRAMD1C | c.953-2618G>T | Intron (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- GRHPR | c.734+30del | Intron (DEL) | VAF 33/235 reads (14%) | called by mutect2, pindel, varscan2
- GUCY2EP | n.1737G>T | RNA (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- HAS2-AS1 | n.774T>G | RNA (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.582C>G | RNA (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- IGKV3-20 | c.-8A>T | 5'UTR (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- ITGAD | c.859-23C>A | Intron (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- KLF8 | c.-70A>G | 5'UTR (SNP) | VAF 6/60 reads (10%) | catalogued as rs1299377998; called by muse, varscan2
- LGI4 | c.793+29T>C | Intron (SNP) | VAF 14/127 reads (11%) | catalogued as rs1226584365; called by muse, mutect2, varscan2
- MPRIP | c.2164-4310G>T | Intron (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- NBPF11 | c.-548-2842G>T | Intron (SNP) | VAF 36/258 reads (14%) | called by muse, mutect2, varscan2
- NDUFS4 | c.177+1345C>T | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1001+10G>T | Intron (SNP) | VAF 30/422 reads (7%) | called by muse, mutect2
- NRXN1 | c.3365-109775C>T | Intron (SNP) | VAF 26/532 reads (5%) | catalogued as COSV58434961; called by muse, mutect2
- NUP210P1 | n.392G>T | RNA (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- OBSCN | c.5138-1739G>T | Intron (SNP) | VAF 72/551 reads (13%) | called by muse, mutect2, varscan2
- OR4C4P | n.840T>C | RNA (SNP) | VAF 8/77 reads (10%) | catalogued as rs74415452; called by mutect2, varscan2
- PCDHGA3 | c.2425-67345A>T | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- PPIAP58 | chr19:29923702 G>T | 3'Flank (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- PRRG3 | c.8-14G>T | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- RNF17 | c.1240+847C>A | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- SCN3B | c.-21G>T | 5'UTR (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- SEC14L1 | c.-240+45G>T | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- SEPTIN5 | c.55-2330G>T | Intron (SNP) | VAF 26/249 reads (10%) | called by muse, mutect2, varscan2
- SHANK2 | c.1174+33096G>T | Intron (SNP) | VAF 30/584 reads (5%) | called by muse, mutect2
- SLAMF8 | chr1:159841186 C>A | 3'Flank (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- SLC22A7 | c.399+98C>A | Intron (SNP) | VAF 52/304 reads (17%) | called by muse, mutect2, varscan2
- SLIT3 | c.1459+4542G>T | Intron (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- SLIT3 | c.1459+4541G>T | Intron (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- TFCP2 | c.123-6116G>T | Intron (SNP) | VAF 15/423 reads (4%) | called by muse, mutect2
- TOX2 | c.*47G>T | 3'UTR (SNP) | VAF 17/274 reads (6%) | called by muse, mutect2
- UAP1L1 | chr9:137086525 C>A | 3'Flank (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- WDR92 | c.-69C>G | 5'UTR (SNP) | VAF 20/210 reads (10%) | catalogued as rs753884202; called by muse, mutect2
- ZNF486 | c.-103C>A | 5'UTR (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- ZNF783 | c.802+3088C>A | Intron (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- ZNF783 | c.802+3089C>A | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
